Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A01N, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A01N-01A (Primary Tumor).

Diagnosis:

1. Preparation of (left) mammary ablation with fibrocystic mastopathy and ductal hyperplasia, with extensive foci of a lobular neoplasia, partly of the type carcinoma lobulare in situ (CLIS and LN2), combined with a well-differentiated intraductal breast carcinoma (DCIS grade 1) with a partly papillary structure, in transition at two points to an invasive, well-differentiated ductal breast carcinoma (G1, pT1a (2) L0 V0 R0)
2. 13 tumor-free (left axillary) lymph nodes (pN0 0/13).
- * 3. Resected section of the rectum with tumor-free resection margins and with a moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria, with invasion into the lymph vessels, without local lymph node metastases (and with previous liver metastasis, confirmed by a biopsy examination .xxx (G2 pT2, L1 V0 R0 pN0 0/23 pM1 HEP).
4. Tumor-free resected hepatic wedge excision (without further metastatic secondaries of the aforementioned rectal carcinoma) with non-active (possibly nutritive-toxic?) cirrhosis of the liver with focal steatosis.

100 0-3

Adenocarcinoma, NOS 8140/3

Site: rectum C20.9 for 3/31/11

Synchronous allowed

Source: NCI Genomic Data Commons file 956f969b-b9df-4cf3-b3ff-73964bc70105 (TCGA-AG-A01N.4D2D4F1B-3EC2-4283-BECE-8BDDFBE95E5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).